Somatic mutation profile of tumor specimen TCGA-BP-4976-01A (aliquot TCGA-BP-4976-01A-01D-1462-08) from TCGA case TCGA-BP-4976, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 77.7 years (28,380 days).
Specimen TCGA-BP-4976-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20724c07-b2e9-48de-8c4d-7cb7271dff77.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-4976-11A (Solid Tissue Normal), aliquot TCGA-BP-4976-11A-01D-1462-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a73ab263-6ab7-43ea-934e-cb3bc5d47d05

The open-access MAF lists 100 somatic variants for this specimen: 75 protein-altering or splice-affecting, 22 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 22, Frame Shift Del 10, Frame Shift Ins 4, Nonsense Mutation 2, Intron 2, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DCDC2 | c.970dup p.A324Gfs*8 | Frame Shift Ins (INS) | VAF 69/252 reads (27%) | catalogued as rs774115675; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABL2 | c.898G>A p.G300R (on ENST00000502732 / NM_007314.4; = p.G285R on NM_005158.5) | Missense Mutation (SNP) | VAF 66/174 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61011664; called by muse, mutect2, varscan2
- ADAM12 | c.383A>T p.Y128F | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as COSV64103640; called by muse, mutect2, varscan2
- AIMP1 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 90/231 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.682); catalogued as COSV63637961; called by muse, mutect2, varscan2
- ALOXE3 | c.463T>G p.C155G | Missense Mutation (SNP) | VAF 68/187 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV59074401; called by muse, mutect2, varscan2
- ANAPC7 | c.1391T>A p.L464* | Nonsense Mutation (SNP) | VAF 61/173 reads (35%) | catalogued as COSV71443757; called by muse, mutect2, varscan2
- APC2 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs761738313, COSV52016591; called by muse, mutect2
- ASXL3 | c.5150A>C p.E1717A | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.174); catalogued as COSV52460222; called by muse, mutect2, varscan2
- BBOF1 | c.201A>T p.L67F | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV58221039; called by muse, mutect2, varscan2
- CHD4 | c.4630G>A p.V1544I (on ENST00000357008 / NM_001363606.2; = p.V1557I on NM_001273.5) | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.046); catalogued as COSV58896223; called by muse, mutect2, varscan2
- CPNE5 | c.710G>T p.R237I | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.714); catalogued as COSV55195204; called by muse, mutect2, varscan2
- CTNND1 | c.1477G>A p.A493T | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV62382466; called by muse, mutect2, varscan2
- DEPDC5 | c.653T>C p.V218A | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV56692788; called by muse, mutect2, varscan2
- DLC1 | c.3606G>C p.Q1202H (on ENST00000276297 / NM_001348081.2; = p.Q765H on NM_006094.5) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as COSV52293992; called by muse, mutect2, varscan2
- DOCK10 | c.1780C>G p.L594V | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV51356765; called by muse, mutect2, varscan2
- FAM86B1 | c.485A>T p.Q162L | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.777); catalogued as COSV58668070; called by mutect2, varscan2
- GJC1 | c.539A>T p.Q180L | Missense Mutation (SNP) | VAF 66/207 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57910620; called by muse, mutect2, varscan2
- HEBP2 | c.593del p.N198Mfs*26 | Frame Shift Del (DEL) | VAF 30/105 reads (29%) | catalogued as rs769528102, COSV100874953; called by mutect2, pindel, varscan2
- IGF2R | c.1321G>T p.D441Y | Missense Mutation (SNP) | VAF 51/124 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as COSV63627021, COSV63633673; called by muse, mutect2, varscan2
- IGKV3-7 | c.209A>G p.Y70C | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as rs1180865594; called by muse, mutect2, varscan2
- ITIH2 | c.628G>C p.E210Q | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.395); catalogued as COSV64432353, COSV64432827; called by muse, mutect2, varscan2
- JAK2 | c.1796G>T p.S599I | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67589267; called by muse, mutect2, varscan2
- KCNS3 | c.1390G>A p.D464N | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs150320186; called by muse, mutect2, varscan2
- KRT6C | c.1114G>C p.D372H | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV52876775; called by muse, mutect2, varscan2
- LAMA1 | c.2177G>A p.G726D | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV67533394; called by muse, mutect2, varscan2
- LRP1B | c.13058G>T p.G4353V | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV67196440; called by muse, mutect2, varscan2
- LYST | c.5178del p.F1726Lfs*2 | Frame Shift Del (DEL) | VAF 18/58 reads (31%) | catalogued as COSV101090459; called by mutect2, pindel, varscan2
- METTL9 | c.913T>A p.Y305N | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51678590; called by muse, mutect2, varscan2
- MMUT | c.593del p.N198Ifs*3 | Frame Shift Del (DEL) | VAF 31/100 reads (31%) | catalogued as CD109983; called by mutect2, pindel, varscan2
- MPST | c.541G>T p.V181L (on ENST00000341116 / NM_001369904.2; = p.V201L on NM_021126.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.096); catalogued as COSV62017308; called by muse, mutect2
- MPV17L | c.508A>T p.S170C (on ENST00000396385 / NM_001128423.2; = p.E146V on NM_173803.4) | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV55008162; called by muse, mutect2, varscan2
- NLRX1 | c.1013C>T p.S338L | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV52702274; called by muse, mutect2, varscan2
- OPRL1 | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61091132; called by muse, mutect2, varscan2
- PHLDB3 | c.980G>A p.C327Y | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52668224; called by muse, mutect2, varscan2
- PLEKHA2 | c.74T>A p.F25Y | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66242237; called by muse, mutect2, varscan2
- POLR2B | c.1582T>G p.L528V | Missense Mutation (SNP) | VAF 63/201 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58899062; called by muse, mutect2, varscan2
- PPFIA1 | c.2459G>A p.G820E | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.103); catalogued as COSV54132539; called by muse, mutect2, varscan2
- PPP1R21 | c.574G>T p.E192* | Nonsense Mutation (SNP) | VAF 11/41 reads (27%) | catalogued as COSV54282723; called by muse, mutect2, varscan2
- PRLR | c.1337C>T p.A446V | Missense Mutation (SNP) | VAF 88/183 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as rs1490023814, COSV51493677; called by muse, mutect2, varscan2
- PRPF4B | c.781G>T p.D261Y | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.172); catalogued as rs756647734, COSV61783211; called by muse, mutect2, varscan2
- RPL18A | c.77C>A p.P26H | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV55829803; called by muse, mutect2, varscan2
- RSKR | c.350C>G p.S117C | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV56381347; called by muse, mutect2, varscan2
- RUFY4 | c.1556A>C p.E519A | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV60246498; called by muse, mutect2, varscan2
- SAMD9 | c.2905A>C p.K969Q | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV66073589; called by muse, mutect2, varscan2
- SCAF11 | c.3862C>A p.Q1288K | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs990778395, COSV65475422; called by muse, mutect2
- SCAF11 | c.3860A>G p.Q1287R | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV65475427; called by muse, mutect2
- SEZ6L | c.2338G>A p.V780M | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs375640180; called by muse, mutect2, varscan2
- SIGLEC9 | c.199A>C p.N67H | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as COSV51582997; called by muse, mutect2, varscan2
- SLC15A3 | c.682C>A p.L228M | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.622); catalogued as COSV57171071, COSV57171699; called by muse, mutect2, varscan2
- SLC25A24 | c.574G>A p.G192R | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs778013594, COSV51446306; called by muse, mutect2, varscan2
- SLC26A8 | c.98A>T p.E33V | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV62884944; called by muse, mutect2, varscan2
- SLC45A3 | c.826G>A p.V276M | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.769); catalogued as rs138897809; called by muse, mutect2, varscan2
- SSH1 | c.1735G>A p.G579S | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.024); catalogued as COSV58454938; called by muse, mutect2, varscan2
- SYPL2 | c.610G>C p.G204R | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV63994742; called by muse, mutect2, varscan2
- TGFBI | c.864C>G p.I288M | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV59350380, COSV59352496; called by muse, mutect2, varscan2
- UBR3 | c.4186A>G p.I1396V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV55845912; called by muse, mutect2, varscan2
- UBR4 | c.5045G>A p.C1682Y | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64384183; called by muse, mutect2, varscan2
- VIPR1 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 27/38 reads (71%) | SIFT tolerated (0.88); PolyPhen benign (0.007); catalogued as COSV57296701; called by muse, mutect2, varscan2
- XRN2 | c.1005G>C p.W335C | Missense Mutation (SNP) | VAF 100/357 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65868481; called by muse, mutect2, varscan2
- ZBTB40 | c.902A>G p.E301G | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV65144796; called by muse, mutect2, varscan2
- ZFR | c.1439C>T p.T480I | Missense Mutation (SNP) | VAF 41/226 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV54051125; called by muse, mutect2, varscan2
- ZNF16 | c.1708C>A p.L570M | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV52762955; called by muse, mutect2, varscan2
- ZNF343 | c.1455G>C p.R485S | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.587); catalogued as COSV53853057, COSV53854445; called by muse, mutect2, varscan2
- DDX39B | c.529_530dup p.A178* | Frame Shift Ins (INS) | VAF 15/75 reads (20%) | called by mutect2, pindel, varscan2
- FBH1 | c.2664_2672del p.D888_K891delinsE (on ENST00000362091 / NM_178150.3; = p.D939_K942delinsE on NM_032807.4) | In Frame Del (DEL) | VAF 22/66 reads (33%) | called by mutect2, pindel, varscan2
- MED30 | c.512del p.N171Mfs*6 | Frame Shift Del (DEL) | VAF 14/39 reads (36%) | called by mutect2, pindel, varscan2
- N4BP1 | c.636_639del p.T213Sfs*10 | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | called by pindel, varscan2
- PARP12 | c.763del p.R255Efs*73 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | called by mutect2, pindel
- PRUNE2 | c.5012C>T p.A1671V | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.019); called by muse, mutect2
- SDR39U1 | c.12dup p.V5Cfs*39 | Frame Shift Ins (INS) | VAF 31/143 reads (22%) | called by mutect2, pindel, varscan2
- SEPHS1 | c.103dup p.Q35Pfs*20 | Frame Shift Ins (INS) | VAF 52/173 reads (30%) | called by mutect2, pindel, varscan2
- SH2D3A | c.169del p.A57Pfs*40 | Frame Shift Del (DEL) | VAF 8/33 reads (24%) | called by mutect2, pindel, varscan2
- SHMT2 | c.585del p.Y195* | Frame Shift Del (DEL) | VAF 31/107 reads (29%) | called by mutect2, pindel, varscan2
- SNX14 | c.1010del p.L337* (on ENST00000314673 / NM_001350535.1; = p.L293* on NM_020468.5 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 11/37 reads (30%) | called by mutect2, pindel, varscan2
- VHL | c.443_451delinsG p.F148Cfs*23 | Frame Shift Del (DEL) | VAF 58/127 reads (46%) | called by pindel, varscan2*
- ACAD10 | c.2661C>T p.V887= | Silent (SNP) | VAF 76/228 reads (33%) | catalogued as COSV58154787; called by muse, mutect2, varscan2
- AQP11 | c.732T>C p.S244= | Silent (SNP) | VAF 69/193 reads (36%) | catalogued as COSV57992111; called by muse, mutect2, varscan2
- BRAT1 | c.2316G>C p.V772= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as COSV61394462; called by muse, mutect2, varscan2
- BRPF1 | c.2412C>G p.G804= | Silent (SNP) | VAF 19/23 reads (83%) | catalogued as COSV57403607; called by muse, mutect2, varscan2
- CGRRF1 | c.624C>T p.C208= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as COSV53595803; called by muse, mutect2, varscan2
- CYLC1 | c.813T>C p.N271= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as COSV61410611; called by muse, mutect2, varscan2
- DOCK2 | c.4629C>T p.F1543= | Silent (SNP) | VAF 62/122 reads (51%) | catalogued as rs759798277, COSV56946841; called by mutect2, varscan2
- FAM160A2 | c.2592C>A p.L864= (on ENST00000449352 / NM_001098794.2; = p.L878= on NM_032127.4) | Silent (SNP) | VAF 46/144 reads (32%) | catalogued as COSV56410100; called by muse, mutect2, varscan2
- FZR1 | c.1281C>A p.V427= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as COSV58050647; called by muse, mutect2, varscan2
- GPR152 | c.927G>T p.V309= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV56885266; called by muse, mutect2, varscan2
- HELB | c.3240G>A p.K1080= | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as COSV56072724; called by muse, mutect2, varscan2
- MTERF2 | c.771A>G p.Q257= | Silent (SNP) | VAF 39/138 reads (28%) | catalogued as rs1453433101, COSV53527078; called by muse, mutect2, varscan2
- PAX8 | c.249G>A p.V83= | Silent (SNP) | VAF 10/306 reads (3%) | catalogued as COSV54506954; called by muse, mutect2
- SEC24C | c.732C>T p.P244= | Silent (SNP) | VAF 32/115 reads (28%) | catalogued as COSV59540491; called by muse, mutect2, varscan2
- SFRP4 | c.150G>T p.T50= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV52258837, COSV52260517; called by muse, mutect2, varscan2
- SMAD7 | c.618T>C p.S206= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs1165521957, COSV50988926; called by muse, mutect2, varscan2
- SPRYD7 | c.396T>C p.I132= | Silent (SNP) | VAF 30/72 reads (42%) | catalogued as COSV62523801; called by muse, mutect2, varscan2
- SRC | c.591C>A p.A197= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as COSV62439412; called by muse, mutect2, varscan2
- TAF5L | c.321G>T p.L107= | Silent (SNP) | VAF 35/82 reads (43%) | catalogued as COSV51077901; called by muse, mutect2, varscan2
- TTN | c.68574A>T p.L22858= (on ENST00000591111; = p.L15434= on NM_003319.4) | Silent (SNP) | VAF 36/111 reads (32%) | catalogued as COSV59931349; called by muse, mutect2, varscan2
- TUBAL3 | c.741C>G p.A247= | Silent (SNP) | VAF 6/87 reads (7%) | catalogued as COSV66814045; called by muse, mutect2
- WWP1 | c.2313A>G p.E771= | Silent (SNP) | VAF 35/101 reads (35%) | catalogued as COSV55357211; called by muse, mutect2, varscan2
- IMPDH1 | chr7:128409461 T>C | 5'Flank (SNP) | VAF 42/151 reads (28%) | catalogued as COSV58315280; called by muse, mutect2, varscan2
- NACA | c.71-3795T>C | Intron (SNP) | VAF 9/36 reads (25%) | catalogued as COSV63268211; called by muse, mutect2, varscan2
- TTBK1 | c.1986+6361C>T | Intron (SNP) | VAF 7/15 reads (47%) | catalogued as rs985636685, COSV99444790; called by muse, mutect2
